Somatic mutation profile of tumor specimen TCGA-CM-5863-01A (aliquot TCGA-CM-5863-01A-21D-1835-10) from TCGA case TCGA-CM-5863, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.6 years (22,127 days).
Specimen TCGA-CM-5863-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0957168-e3b6-41b0-a539-b4635e322221.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5863-10A (Blood Derived Normal), aliquot TCGA-CM-5863-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68eb5f94-0f57-494d-b54b-e7747bd89175

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 37, Silent 12, Frame Shift Del 4, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/112 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 4/41 reads (10%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by mutect2, varscan2
- APBA2 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs574988993, COSV68789135; called by muse, mutect2, varscan2
- APC | c.4466del p.L1489Yfs*18 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as COSV57327796; called by mutect2, pindel, varscan2
- CACNA2D3 | c.2880G>T p.Q960H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55546041; called by muse, varscan2
- CAMK2B | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs201975711, COSV51661444; called by muse, mutect2, varscan2
- CMC4 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1460522039, COSV62899583; called by muse, mutect2, varscan2
- CNTD1 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV59312068; called by muse, mutect2, varscan2
- DIS3L | c.3133C>T p.L1045F (on ENST00000319212 / NM_001143688.3; = p.L962F on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV99972438; called by muse, mutect2
- EDARADD | c.178A>C p.I60L (on ENST00000334232 / NM_145861.4; = p.I50L on NM_080738.4) | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100512557, COSV62063033; called by muse, varscan2
- EFEMP1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs1307987501, COSV62616481; called by muse, mutect2, varscan2
- FAM83G | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1445162570, COSV58758875; called by muse, mutect2, varscan2
- FBLN1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs746187852, COSV53048686; called by mutect2, varscan2
- GPR84 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs745592286, COSV57209810, COSV57209970; called by muse, mutect2, varscan2
- HEG1 | c.3907C>T p.R1303C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753638813, COSV60762876; called by muse, mutect2, varscan2
- HS3ST4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs867965756, COSV58804388; called by muse, mutect2, varscan2
- ITGA5 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs377040337; called by muse, mutect2, varscan2
- KAZN | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1357860418, COSV101056594; called by muse, mutect2
- KCNJ6 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV55713468; called by muse, mutect2, varscan2
- KDM5C | c.2949G>A p.W983* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100949538, COSV64765576; called by muse, mutect2, varscan2
- LRRC14B | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs781723149, COSV52048769; called by muse, mutect2, varscan2
- MFSD13A | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145950496; called by muse, mutect2, varscan2
- MRPS30 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV50181486, COSV50181754; called by muse, mutect2
- MYH2 | c.5305G>A p.A1769T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs550869991, COSV55439897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAP1L3 | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV100220524; called by muse, mutect2
- OSR1 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV55345743; called by muse, mutect2, varscan2
- PDE8A | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104402980, COSV59637577; called by mutect2, varscan2
- PPP1R18 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs753123312, COSV51296614; called by muse, mutect2, varscan2
- PRR23B | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs768770380, COSV61494861; called by muse, mutect2, varscan2
- RAD50 | c.3826C>T p.L1276F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV54756548; called by muse, mutect2
- RICTOR | c.2743G>T p.D915Y | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV57123387; called by muse, mutect2, varscan2
- RPGR | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV58832290; called by muse, mutect2
- SF3B1 | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100135201; called by muse, mutect2, varscan2
- SLC9A6 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV65788410; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs746109620; called by mutect2, varscan2
- SYNE1 | c.20465C>A p.T6822N (on ENST00000367255 / NM_182961.4; = p.T6751N on NM_033071.3) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs777151673, COSV54907858, COSV99572112; called by muse, mutect2, varscan2
- SYNE1 | c.4851G>T p.R1617S (on ENST00000367255 / NM_182961.4; = p.R1624S on NM_033071.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV99572118; called by muse, mutect2, varscan2
- SYNE1 | c.4850G>T p.R1617M (on ENST00000367255 / NM_182961.4; = p.R1624M on NM_033071.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99572124; called by mutect2, varscan2
- TGFBI | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs192398905; called by muse, mutect2, varscan2
- TIMELESS | c.1403T>C p.I468T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57509747; called by muse, varscan2
- TLR8 | c.9C>A p.N3K (on ENST00000218032 / NM_138636.5; = p.N21K on NM_016610.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV54318476; called by mutect2, varscan2
- WDR49 | c.76G>T p.D26Y (on ENST00000308378 / NM_001366158.1; = p.D367Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57709570; called by muse, mutect2, varscan2
- COPA | c.512del p.N171Tfs*11 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, varscan2
- MGA | c.6061_6062del p.L2021Efs*2 (on ENST00000219905 / NM_001164273.1; = p.L1812Efs*2 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by pindel, varscan2
- ACSL4 | c.2007C>T p.I669= (on ENST00000340800 / NM_022977.2; = p.I628= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs1278087781, COSV100538787, COSV100539166; called by mutect2, varscan2
- ARAF | c.1587G>A p.P529= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs1261254398, COSV51693135; called by muse, mutect2, varscan2
- CLIP1 | c.319C>A p.R107= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100211422, COSV56802942; called by muse, mutect2, varscan2
- ENOSF1 | c.261C>T p.V87= (on ENST00000340116 / NM_001354066.2; = p.V39= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs139918997; called by mutect2, varscan2
- FAM124A | c.543C>T p.D181= (on ENST00000322475 / NM_001242312.2; = p.D217= on NM_145019.4) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV54477205; called by muse, mutect2, varscan2
- FLNB | c.6237C>T p.H2079= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs767109451, COSV55881849; called by mutect2, varscan2
- GPR174 | c.129A>G p.V43= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99338239; called by muse, mutect2, varscan2
- INF2 | c.2838G>A p.E946= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV53033211; called by muse, mutect2, varscan2
- ITPKB | c.912G>A p.T304= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1411715539, COSV55263076; called by muse, mutect2, varscan2
- KCNA1 | c.1098G>A p.A366= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV66836738, COSV66837556; called by muse, varscan2
- NSD1 | c.2445C>T p.C815= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs764456592, COSV100729612; called by mutect2, varscan2
- PCARE | c.2190C>T p.S730= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs369820535; called by muse, mutect2, varscan2
